Somatic mutation profile of tumor specimen TARGET-30-PARKGJ-01A (aliquot TARGET-30-PARKGJ-01A-01D) from TARGET case TARGET-30-PARKGJ, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.4 years (1,616 days).
Specimen TARGET-30-PARKGJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bf73bdbd-e8f1-49c1-b7ac-41a7a72e350f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PARKGJ-10A (Blood Derived Normal), aliquot TARGET-30-PARKGJ-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b96adbc9-368f-43d4-a308-6c7cceb9e642

The open-access MAF lists 30 somatic variants for this specimen: 21 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 8, Nonsense Mutation 2, Frame Shift Del 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP10A | c.2260C>T p.R754W | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755143094, COSV63523111; called by muse, mutect2, varscan2
- BSN | c.3248C>A p.A1083D | Missense Mutation (SNP) | VAF 30/35 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56528929; called by muse, mutect2, varscan2
- CPXM1 | c.2009T>A p.M670K | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as rs766560640, COSV66045469, COSV66046910; called by muse, mutect2, varscan2
- CTAGE1 | c.1925T>A p.L642* | Nonsense Mutation (SNP) | VAF 98/200 reads (49%) | catalogued as COSV66945237; called by muse, mutect2, varscan2
- CYTH2 | c.551C>G p.T184R | Missense Mutation (SNP) | VAF 4/77 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57310072; called by muse, mutect2
- GIMAP8 | c.907G>T p.A303S | Missense Mutation (SNP) | VAF 40/163 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV56234520; called by muse, mutect2, varscan2
- GRAMD2A | c.584G>A p.G195E | Missense Mutation (SNP) | VAF 45/104 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs867459791, COSV59035727; called by muse, mutect2, varscan2
- ILF3 | c.1043A>G p.K348R | Missense Mutation (SNP) | VAF 35/96 reads (36%) | SIFT tolerated (0.36); PolyPhen benign (0.014); catalogued as COSV51562922; called by muse, mutect2, varscan2
- LRIF1 | c.2080G>T p.E694* | Nonsense Mutation (SNP) | VAF 55/115 reads (48%) | catalogued as COSV63898529; called by muse, mutect2, varscan2
- LSR | c.63C>A p.H21Q | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.075); catalogued as COSV61554959, COSV61556010; called by muse, mutect2, varscan2
- LTV1 | c.559G>A p.D187N | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.208); catalogued as COSV62536793; called by muse, mutect2, varscan2
- MOGAT1 | c.661C>G p.L221V | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1386005271, COSV71480159; called by muse, mutect2, varscan2
- NBAS | c.2575C>A p.Q859K | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.034); catalogued as COSV55739404; called by muse, mutect2, varscan2
- OR5AR1 | c.238A>G p.R80G | Missense Mutation (SNP) | VAF 83/299 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.258); catalogued as COSV57255550; called by muse, mutect2, varscan2
- PCLO | c.8174G>C p.G2725A | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.453); catalogued as COSV61671465; called by muse, mutect2, varscan2
- PLCB2 | c.986C>G p.T329S | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV53038590; called by muse, mutect2, varscan2
- PRG2 | c.254A>G p.K85R | Missense Mutation (SNP) | VAF 77/221 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.014); catalogued as COSV61294255; called by muse, mutect2, varscan2
- PSG4 | c.818G>T p.W273L | Missense Mutation (SNP) | VAF 120/128 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54941712; called by muse, mutect2, varscan2
- LRRCC1 | c.2101del p.T701Qfs*9 | Frame Shift Del (DEL) | VAF 21/60 reads (35%) | called by mutect2, pindel, varscan2
- SLC36A2 | c.752del p.P251Qfs*9 | Frame Shift Del (DEL) | VAF 20/119 reads (17%) | called by mutect2, pindel, varscan2
- URB2 | c.1531C>G p.L511V | Missense Mutation (SNP) | VAF 8/142 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.745); called by muse, mutect2
- ADGRL4 | c.1065T>C p.F355= | Silent (SNP) | VAF 12/24 reads (50%) | catalogued as COSV66066563; called by muse, mutect2, varscan2
- CD8A | c.150G>A p.P50= | Silent (SNP) | VAF 34/128 reads (27%) | catalogued as COSV52159740; called by muse, mutect2, varscan2
- CHL1 | c.2595G>T p.V865= (on ENST00000397491 / NM_001253387.1; = p.V881= on NM_006614.4) | Silent (SNP) | VAF 15/19 reads (79%) | catalogued as COSV56608096; called by muse, mutect2, varscan2
- FAM117A | c.495G>A p.T165= | Silent (SNP) | VAF 52/245 reads (21%) | catalogued as rs936996803, COSV53634245; called by muse, mutect2, varscan2
- OR4N5 | c.339C>T p.F113= | Silent (SNP) | VAF 46/130 reads (35%) | catalogued as rs1566559795, COSV61321436; called by muse, mutect2, varscan2
- PODXL2 | c.360T>C p.F120= | Silent (SNP) | VAF 12/29 reads (41%) | catalogued as COSV61066648; called by muse, mutect2, varscan2
- SIM1 | c.165G>A p.V55= | Silent (SNP) | VAF 22/36 reads (61%) | catalogued as rs1456655359, COSV53497341; called by muse, mutect2, varscan2
- SNCAIP | c.2397C>A p.L799= | Silent (SNP) | VAF 20/45 reads (44%) | catalogued as COSV54422724; called by muse, mutect2, varscan2
- BIRC8 | n.1137T>A | RNA (SNP) | VAF 45/97 reads (46%) | catalogued as COSV70348079; called by muse, mutect2, varscan2
